Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65D, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65D-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY -

FIFTEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/15).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY -

NINETEEN LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/19).

PART 3: PROSTATE, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4+4 = 8, WITH PROMINENT DUCTAL FEATURES.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 15% OF THE TOTAL TISSUE EVALUATED.
- C. THE CARCINOMA MEASURES 1.5 CM IN GREATEST NODULAR DIMENSION.
- D. MULTIFOCAL ESTABLISHED EXTRACAPSULAR EXTENSION BY THE CARCINOMA IS SEEN. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF THE RIGHT POSTERIOR APEX (SLIDE 3X), RIGHT MID POSTERIOR (SLIDE 3Y), RIGHT POSTERIOR BASE (SLIDES 3Z, 3AA), RIGHT POSTERIOR LEVEL 8 (SLIDE 3TT) AND LEFT POSTERIOR BASE (SLIDE 3EE).
- E. ALL INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- F. BILATERAL SEMINAL VESICLES, NO CARCINOMA SEEN.
- G. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) SEEN.
- I. TNM STAGE: T3a M0 NX.
- J. HISTOLOGIC GRADE G3 (POORLY DIFFERENTIATED).

PART 4: BLADDER, POSTERIOR BLADDER NECK, EXCISION -

UROTHELIUM-LINED BLADDER TISSUE, NO EVIDENCE OF CARCINOMA SEEN.

PART 5: RIGHT SUPERIOR PEDICLE, EXCISION -

PROSTATIC CARCINOMA IDENTIFIED IN A BACKGROUND OF FIBROVASCULAR AND NERVE TISSUE.

PART 6: RIGHT NEUROVASCULAR BUNDLE, EXCISION -

PROSTATIC CARCINOMA IDENTIFIED IN A BACKGROUND OF FIBROVASCULAR AND NERVE TISSUE.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 10.64
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
	Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	85%
WEIGHT OF PROSTATE:	54.32gm
TUMOR SIZE:	Maximum dimension: 1.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	34
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site: Prostate NOS
261.9

5/16/13

PATIENT HISTORY:

The patient is a -year-old male with a history of PSA value of 10.64 ng/ml. The patient also has a history of biopsy on this biopsy reveals: Prostatic adenocarcinoma - left apex, left mid, left base (Gleason score 4+4 = 8), and right mid (Gleason score 3+4=7). No additional patient history is provided.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

Source: NCI Genomic Data Commons file e1f6a5d2-48e4-4d49-ac89-9b538161f95d (TCGA-EJ-A65D.AD3DEFE9-4977-4334-A197-159F043C92A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).